Gene-level copy-number profile of tumor specimen TCGA-JY-A6F8-01A from TCGA case TCGA-JY-A6F8, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 56.3 years (20,550 days).
Specimen TCGA-JY-A6F8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.425f1eca-1a99-4391-ade6-d2b1c93682c9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-JY-A6F8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ed5069bd-a56d-4729-8c2f-8c1c0026534d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,672; copy number 2: 7,159; copy number 3: 28,211; copy number 4: 14,751; copy number 5: 4,427; copy number 6: 1,299; copy number 7: 256; copy number 8: 246; copy number 9: 80; copy number 10: 98; copy number 11: 21; copy number 12: 51; copy number 14: 58; copy number 15: 390; copy number 16: 42; copy number 17: 27; copy number 18: 16; copy number 19: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-JY-A6F8-01A-11D-A33D-01): tumor purity 0.71, ploidy 3.56, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,301 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:7,192,538–7,742,836, 1 gene, copy number 8 (within-gene range 5–8): SORCS2.
- chr4:7,430,285–30,721,970, 305 genes, copy number 8–9 (broad region; genes not listed).
- chr4:30,776,257–30,793,970, 1 gene, copy number 9: AC097716.1.
- chr8:2,726,956–15,325,569, 333 genes, copy number 14–19 (within-gene range 2–19) (broad region; genes not listed).
- chr8:105,929,126–141,002,216, 386 genes, copy number 10–18 (within-gene range 6–18) (broad region; genes not listed).
- chr13:60,012,734–60,613,734, 9 genes, copy number 7: DIAPH3-AS1, RN7SL375P, DIAPH3-AS2, RNY4P28, LINC00434, TARDBPP2, AL359920.1, TDRD3, RNA5SP31.
- chr13:60,636,888–60,733,600, 2 genes, copy number 7: EIF4A1P6, AL161901.1.
- chr13:70,564,267–73,995,056, 34 genes, copy number 7: AL445264.1, MTCL1P1, LINC00348, RABEPKP1, DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21, AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1.
- chr13:74,434,538–81,302,407, 91 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr13:87,219,004–88,630,397, 19 genes, copy number 8: UBBP5, LIN28AP2, AL360267.2, AL360267.1, MIR4500HG, AL355578.1, MIR4500, SLITRK5, AL445647.2, LINC00397, AL445647.1, TET1P1, LINC00373, RPL29P29, AL355677.1, LINC00433, AL445984.2, AL445984.1, LINC00560.
- chr13:94,436,811–101,059,286, 120 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 381. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
